Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ADIN, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ADIN-TTM1-A (Metastatic).

[page 1 of 22]
Pat. Name	Adm. Date	Sex	Age	Location	Allergies	Relationship	Adm. Diagnosis
⊕ [REDACTED]	[REDACTED] +1081	[REDACTED]	[REDACTED]	[REDACTED]	NKA		(189.2) MALIGN NEOPL URETER

Go to...

Report for [REDACTED] (MRN: [REDACTED])

TEST: Srg Path Rpt [REDACTED]
Collected Date & Time [REDACTED] +0

Result Name	Results	Units	Reference Range
Surg Path Report (NOTE)	(NOTE)(..)		

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med Rec #: [REDACTED]

Specimen #: [REDACTED]

Final Diagnosis:

A. Omentum, omentectomy: METASTATIC ADENOCARCINOMA WITH PAPILLARY FEATURES.

B. Uterus, cervix, bilateral tubes and ovaries, total abdominal hysterectomy and bilateral salpingo-oophorectomy:

- ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE WITH PAPILLARY FEATURES, FIGO GRADE II OF III, MULTIFOCAL, INVOLVING BOTH THE ANTERIOR WALL (2.0 X 1.8 X 1.5 CM, LEFT CORNU) AND POSTERIOR WALL (3.5 X 1.8 X 1.2 CM,

LOWER UTERINE SEGMENT), INVADING TO A MAXIMUM DEPTH OF 0.7 CM OF A 1.2 CM MYOMETRIUM, AND EXTENDING TO INVOLVE THE ENDOCERVICAL/LOWER UTERINE SEGMENT TRANSITION ZONE.

- RIGHT OVARY WITH METASTATIC ADENOCARCINOMA.

- LEFT OVARY WITH METASTATIC ADENOCARCINOMA.

- BILATERAL FALLOPIAN TUBES WITH NO PATHOLOGIC CHANGE.

- METASTATIC ADENOCARCINOMA INVOLVING THE LEFT PARAMETRIUM.

- RIGHT PARAMETRIUM WITH NO PATHOLOGIC CHANGE, NEGATIVE FOR CARCINOMA.

- IMMUNOHISTOCHEMICAL STUDIES DEMONSTRATE FOCAL, WEAK TUMOR CELL POSITIVITY FOR BOTH ESTROGEN RECEPTOR (ER) AND PROGESTERONE RECEPTOR (PR).

C. Left pelvic lymph node, excision: METASTATIC ADENOCARCINOMA TO THREE OF SIX LYMPH NODES. (3/6)

D. Right pelvic lymph node, excision: METASTATIC ADENOCARCINOMA TO ONE OF FOUR LYMPH NODES. (1/4)

E. Right pelvic peritoneum, excision: FRAGMENT OF FIBROADIPOSE TISSUE WITH METASTATIC ADENOCARCINOMA.

F. Left periaortic node, excision: METASTATIC ADENOCARCINOMA TO TWO OF TWO LYMPH NODES. (2/2)

G. Appendix, appendectomy:

- METASTATIC ADENOCARCINOMA INVOLVING THE PERIAPPENDICEAL MESENTERY.

- APPENDIX WITH NO PATHOLOGIC CHANGE, NEGATIVE FOR CARCINOMA.

- ONE REACTIVE LYMPH NODE, NEGATIVE FOR CARCINOMA. (0/1)

SYNOPTIC SUMMARY: Endometrium, Hysterectomy

Macroscopic

Specimen Type: Radical hysterectomy (includes parametria)

Tumor Size

[page 2 of 22]
Greatest Dimension (cm): 3.5
Tumor Site: Specify location(s): Multifocal, anterior left cornu and posterior lower uterine segment
Other Organs Present : Right ovaryLeft ovaryRight fallopian tubeLeft fallopian tube

Microscopic

Histologic Type: Endometrioid adenocarcinoma, not otherwise characterized

Histologic Grade: G2 6% to 50% nonsquamous solid growth

Lymph Node Totals

Number Examined: 13

Number Involved: 6

Myometrial Invasion: Invasion present

Depth of Invasion (mm): 7

Myometrial thickness (mm): 12

Percentage Invasion: 58.3

AJCC Stage

Primary Tumor (pT): pT3b (IIIB) Involvement of vagina (direct extension or metastasis), rectal or bladder wall (without mucosal involvement), or pelvic wall(s) (frozen pelvis)
Regional Lymph Nodes (pN): pN1 (IIIC): Regional lymph node metastasis
Distant Metastasis (pM): pMX Cannot be assessed

***Electronically Signed Out By [REDACTED]

Procedures/Addenda:

SSO Sendout Test [REDACTED] (N/C)

Date Ordered: [REDACTED]

+0 Status:

Signed Out

Date Complete: +225 [REDACTED]

By: [REDACTED]

Date Reported: +225 [REDACTED]

Interpretation

{Not Entered}

Results-Comments

[REDACTED] UTERUS SENT TO [REDACTED] FOR ANALYSIS.

Specimen site: Uterus

ChemoFx

Testing Information

Single Agents: 8

Combination Agents: 3

IN VITRO RESPONSE SUMMARY Responsive Intermediate Response Non-Responsive

CARBOPLATIN/DOCETAXEL

GEMCITABINE

CARBOPLATIN/GEMCITABINE

CARBOPLATIN

CISPLATIN

CARBOPLATIN/PACLITAXEL

PACLITAXEL

TOPOTECAN

ETOPOSIDE

DOXORUBICIN

DOCETAXEL

Laboratory Director: [REDACTED]

Intraoperative Pathology Consultation:

A. Omentum: METASTATIC CARCINOMA WITH PAPILLARY FEATURES.
WAS COMMUNICATED TO THE OPERATING AT [REDACTED]

THIS DIAGNOSIS
(FROZEN SECTION)

[page 3 of 22]
DIAGNOSIS)

Clinical Information:

ENDOMETRIAL CA

Specimen(s) Submitted:

A: Omentum

B: Uterus, cervix, bilateral tubes and ovaries

C: Left pelvic lymph node

D: Right pelvic lymph node

E: Tumor from right pelvic peritoneum

F: Left periaortic node

G: Tumor from mesentery of the appendix and appendix

Gross Description:

A. Omentum: Received fresh for intraoperative consultation is a 22.0 x 16.0 x 1.5 cm flat segment of tan yellow to tan pink fatty omental tissue with multiple firm nodules ranging in size from 0.9 cm to 2.1 cm in greatest dimension, each of which has a homogenous gritty cut surface. The nodules are representatively frozen. Representative sections submitted as follows: AFS1 frozen section residue; A2-5 additional representative sections of omental nodule.

B. Uterus, cervix, bilateral tubes and ovaries: Received fresh without fixative is a 204 g specimen including unopened uterus (11.5 x 5.5 x 4.5 cm), right fallopian tube (5.5 cm in length x 0.5 cm in diameter), right ovary (3.5 x 2.7 x 2.0 cm), left fallopian tube (5.5 cm in length x 0.5 cm in diameter), and left ovary (2.8 x 2.3 x 1.7 cm). The exocervix (3.5 x 3.2 cm) is covered by smooth, glistening, white mucosa. The external is slit like and measures 1.3 cm in maximum dimension. The serosa is dull and there are no adhesions. The serosa of the anterior wall is inked yellow and posterior wall inked black. The uterus sounds to 9.2 cm. The uterus is bivalved to reveal the endocervical canal (3.0 cm in length) with a tan herringbone mucosa and a few cysts. The endometrial cavity (4.0 cm from cornu to cornu, 7.0 cm in length) has a pink tan hemorrhagic endometrium. The cavity is partially filled with brown red to gray tan material. There is a 2.0 x 1.8 cm mass of heaped up pink gray mucosa at left cornu mainly in anterior wall and a 3.5 x 1.8 cm heaped up pink gray mucosa at the lower uterine segment in posterior wall. The mass at left cornu at the areas of deepest invasion measures up to 1.5 cm in depth and at lower uterine segment in posterior wall up to 1.2 cm in depth. They both show gray to pink tan cut surfaces. One representative section from the mass from left cornu is sent to [REDACTED] for precision testing. The uninvolved myometrium measures up to 2.5 cm in maximum thickness. The fallopian tubes are patent and have fimbriated ends. Both ovaries have a partially pale yellow cerebriform and a partially pink tan and smooth outer surface. Sectioning of right ovary reveals several cortical cysts and a gray tan mass with glassy cut surfaces measuring 2.0 cm in maximum dimension. Sectioning of the left ovary reveals several cortical cysts, corpus luteum measuring 1.2 cm in maximum dimension and multiple corpora albicantia. Representative sections are submitted as follows: B1 anterior lip of the cervix; B2 posterior lip of the cervix; B3 transition zone of the anterior wall of the uterus; B4 from posterior wall of the uterus; B5-7 trans mural sections of the anterior wall of the uterus with sections from left cornu showing heaped up mass placed in cassettes B6 and B7. B8-10 from posterior wall of the uterus with sections of heaped up mass at the lower end uterine segment of posterior wall in cassettes B9 and B10. B11 right tube; B12 and 13 right ovary including mass; B14 left fallopian tube; B15 left ovary; B16 right parametrium; B17 left parametrium.

C. Left pelvic lymph node: Received fresh without fixative is a 3.5 x 2.9 x 1.3 cm irregular piece of yellow pink adipose tissue including six lymph nodes ranging from 0.3 to 1.6 cm in maximum individual dimension. They are entirely submitted in cassettes C1 through C4. In cassette C1 each piece

[page 4 of 22]
represents one lymph node. Cassettes C2, 3 and 4 each represent one lymph node, bisected.

D. Right pelvic lymph node: Received fresh without fixative is an irregular piece of yellow pink adipose tissue measuring 3.0 x 2.2 x 0.9 cm in maximum dimensions including five lymph nodes ranging from 0.3 to 1.6 cm in maximum dimension. They are entirely submitted in three cassettes. In cassette D1 each piece represents one lymph node. Cassettes D2 and D3 each represent bisected larger lymph node.

E. Tumor from right pelvic peritoneum: The specimen, received in formalin fixative, consists of an irregular piece of pink tan soft tissue measuring 1.5 x 1.3 x 0.5 cm in maximum dimensions and showing pink tan cut surfaces. Totally embedded, two cassettes.

F. Left periaortic node: Received fresh without fixative are two pink tan lymph nodes measuring 1.0 and 1.2 cm in maximum individual dimension with a sparse amount of yellow pink adipose tissue attached. The smaller lymph node is bisected and entirely submitted in cassette F1. The larger lymph node is trisected and entirely submitted in cassette F2.

G. Tumor from mesentery of appendix: The specimen, received in formalin fixative, consists of a 6.5 cm long grossly unremarkable appendix stapled at the margin of resection averaging 0.5 cm in diameter. The mesoappendix measures 2.3 cm in maximum width and 1.0 cm in maximum thickness and has no nodules or masses. Additionally submitted is an irregular piece of yellow adipose tissue measuring 1.8 x 1.2 x 0.6 cm including one pink tan possible nodule measuring 0.6 cm in maximum dimension. Representative sections of the appendix including the tip are submitted in cassette G1. The entire additional piece including entire possible nodule is trisected and submitted in cassette G2.

A5, AFS1, B17, C4, D3, E2, F2, G2

[page 5 of 22]
Go to...

Report for [REDACTED] (MRN: [REDACTED])

TEST: [REDACTED] General Op Report

Collected Date & Time: [REDACTED] +1

Result Name	Results	Units	Reference Range
[REDACTED] General Op Report			[REDACTED]

OPERATIVE REPORT

NAME: [REDACTED]

DOB: [REDACTED]

PAT. LOC: [REDACTED]

PAT. TYPE: IP

ADMIT: [REDACTED] +0

DISCHARGE:

DATE OF OPERATION: [REDACTED] +0

SURGEON: [REDACTED]

ASSISTANT: [REDACTED]

PREOPERATIVE DIAGNOSIS: ENDOMETRIAL ADENOCARCINOMA

POSTOPERATIVE DIAGNOSIS:

1. METASTATIC STAGE IV-B PAPILLARY ADENOCARCINOMA OF ENDOMETRIUM
2. METASTASIS TO APPENDIX
3. METASTASIS TO OMENTUM
4. METASTASIS TO PARAAORTIC-PARARENAL AND PELVIC LYMPH NODES
5. METASTASIS TO PELVIC PERITONEUM

OPERATION:

1. RADICAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY
2. BILATERAL LYMPH NODE DISSECTION
3. LEFT PARAAORTIC AND PARARENAL LYMPH NODE DISSECTION
4. TOTAL OMENTECTOMY
5. APPENDECTOMY
6. DISSECTION AND EXPLORATION OF RETROPERITONEAL SPACES AND DISSECTION OF BOTH URETERS AND RESECTION OF PELVIC PERITONEAL TUMOR

ANESTHESIA: GENERAL

HISTORY: This is a [REDACTED]-year-old female with history of endometrial carcinoma who was admitted to the hospital by [REDACTED] for treatment. The patient was seen on consultation prior to surgery. Her chart pathology was reviewed and surgery was discussed with the patient in detail. The procedure, risks, and complication and rationale for surgical staging of endometrial carcinoma were discussed with the patient. She was fully informed, understood, and agreed with surgery. I also discussed the surgery with patient together with her husband.

[page 6 of 22]
The patient's history is significant for severe anemia and vaginal bleeding where she was admitted through the emergency room a few weeks ago with very severe anemia and hemoglobin over 4, then it dropped to 2.7. She was given blood transfusion. Then endometrial ablation was performed by Dr. [REDACTED] to minimize and control the bleeding while patient was treated for anemia prior to surgery.

Examination under general anesthesia revealed normal external genitalia and vagina. Rectovaginal examination did reveal a very firm cervix with semifixed uterus. Ovaries were not audible with pelvic examination. On physical examination otherwise, there was no gross abnormalities. Breasts had no nodularity or discharge or bleeding. I was not able to detect or palpate any peripheral lymph nodes. I did discuss the findings with Dr. [REDACTED] and advised him that patient should undergo surgery. Then pending surgical findings, the procedure and tumor resection will be made.

PROCEDURE:

Under general anesthesia in supine position after prep and drape and performing pelvic examination, prophylactic antibiotics and heparin were given. Then Foley catheter was inserted. Compression boots were applied. Then abdomen was opened by Dr. [REDACTED]. Exploration of the abdomen was performed through a midline vertical incision from symphysis pubis to the left umbilicus. Due to extensive intraabdominal metastasis, I was asked by [REDACTED] to take over and perform surgery as outlined above.

On exploration of the abdomen again, the uterus was at least twice normal size. There was tumor metastasis to the right ovary and also there were metastatic nodules at the reflection of the bladder to anterior surface of the uterus. There were multiple small nodules and pelvic peritoneum, especially at the right pelvic peritoneum lying over the right ureter at mid pelvis. There were also a few small tumor nodules in the pelvic peritoneum on the left side of the pelvic and mesentery of the rectosigmoid colon. Pelvic lymph nodes were bilaterally enlarged and adhering to the pelvic vessels including external iliac and internal iliac vein and arteries bilaterally. In the paraaortic area, there were several enlarged metastatic lymph nodes above the inferior mesenteric artery between the artery and the renal vessels.

In upper abdomen, there were no palpable pelvic masses. Large tumor nodule was identified at middle portion of the omentum, which was separately removed and sent to pathology for frozen section with frozen section showing metastatic papillary adenocarcinoma consistent with endometrial primary. Inferior surface of the right and left diaphragm did not show any excrescences or tumor nodules. Surface of the liver was also negative for any metastasis. Gallbladder was empty with no stones. Spleen and kidneys and pancreas were grossly normal. There was metastatic tumor in the mesentery of the appendix and also at the base of the appendix.

After exploration of the abdomen and pelvis with the findings as described, abdomen incision was further extended to the level of umbilicus. Then self-retaining retractor was inserted. Peritoneal washings were obtained and a total omentectomy was performed by removing omentum off of transverse colon and greater curvature of the stomach. Bleeders were ligated. Then open omentum was sent to pathology together with metastatic tumor as described. Then small and large bowel was followed all the way from stomach down to the rectosigmoid region. There were no metastases over the mesentery of small bowel or large bowel otherwise except for the pelvic region.

[page 7 of 22]
At this time uterus was grasped with curved 8 clamps. Then retroperitoneal spaces were opened bilaterally from bifurcation of the aorta down to internal inguinal canal region including paravesical and pararectal spaces were developed. Then round ligaments were clamped, cut, and sutured bilaterally. Ovarian vessels were also clamped and cut at their origination at the pelvic brim. Retroperitoneal spaces were well developed and opened.

Then a portion of the superior portion of the serosa of the bladder was resected and bladder was dissected off of the anterior portion of the uterus and cervix and retracted anteriorly. There was a flat tumor approximately 4 cm in width with 3 cm between the bladder and the anterior portion of the fundus of the uterus, which was transected together by removing portion of the serosa of the bladder. Then round ligaments were also clamped and cut and sutured. Then dissection was carried down to the lower portion of the uterus and parametrium. Ureters were bilaterally dissected off of the pelvic peritoneum and parametrium all the way to the bladder and retracted laterally to prevent any injuries to the ureters.

On the right side, there was a flat tumor lying over the peritoneum of the pelvis, which was adhering over the right ureters; therefore, it required further dissection of the ureter on the right side. Then pelvic peritoneum was removed together with visible tumor. Then uterine vessels were identified at their origination from hypogastric vessels. They were separately clamped, cut, and sutured with Vicryl 0 suture. Uterosacral ligament and cardinal ligaments were also clamped, cut, and sutured medial to the crossover of the ureter with uterine vessels, removing one-third of the uterosacral ligament and cardinal ligament together with uterine specimen.

Then bladder and rectum were further dissected away from anterior and posterior portion of the cervix and upper vagina. Then two Z-clamps were applied one on either corner of cervicovaginal junction just a couple centimeters below the cervicovaginal junction. The specimen was resected and removed with intact uterus, tubes, and ovaries and cervix and portion of the parametrium and upper vagina and sent to pathology. Right ovary was inspected. It was found to have a metastatic tumor but left ovary was grossly normal.

At this time bilateral pelvic lymphadenectomy was performed removing lymphatic tissue from bifurcation of the aorta including common iliac, external iliac, internal iliac, and obturator nodes bilaterally. These were sent to pathology. Bleeders were all controlled and surgical clips were applied for hemostasis. After completion of pelvic surgery, attention was made to the paraaortic region. Retroperitoneal space was opened over the aorta at the mid portion of the abdomen just at the level of inferior mesenteric artery. Then it was dissected all the way up to the level of the duodenum. Retroperitoneal space was well exposed. Then several of left paraaortic-pararenal nodes were removed and sent to pathology. These nodes were grossly metastatic with very friable and enlarged appearance. Bleeders were all controlled and surgical clips were applied to identify the site of metastasis at the paraaortic region.

Then at this time entire abdominal cavity was reexplored. Bleeders were all controlled and sponge count, instrument count, and needle counts were performed. They were all correct. Then abdomen was closed with PDS, loop #0 in two separate section including rectus fascia, rectus muscle, and peritoneum together. Subcutaneous fat was reapproximated with 3-0 Vicryl suture and skin was closed with surgical staples. Patient tolerated the procedure well. She was transferred to recovery room in stable condition.

[page 8 of 22]
Urine output was adequate and clear. Estimated blood loss during entire procedure was approximately 200 cc.

I will review the final pathology and recommend additional treatment as needed.

Job#:

Doc#:

D:

+0

[page 9 of 22]
Click icon to view images for patient.

Pat. Name	Adm. Date	Sex	Age	Location	Relationship	Allergies	Adm. Diagnosis	Birth Date
+	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	Consulting Physician	NKA	(415.19) PULM EMBOL/INFARCT NEC, METASTATIC UTERINE CA	[REDACTED]
	+24							

Report for [REDACTED] (MRN: [REDACTED])

View Images

TEST: CT PELVIS WITH CONTRAST

Collected Date & Time: [REDACTED] +24

Result Name
TRANSCRIPTION
READ BY
CT PELVIS WITH
CONTRAST
CT STUDY OF THE CHEST-

Results [REDACTED]
CT STUDY OF THE CHEST-

Units

Reference Range

Images were obtained through the chest following the intravenous infusion of 140 cc of Optiray 320 contrast.

Images obtained through the lung fields show a small nodule within the superior segment of the right lower lobe measuring 5 mm in diameter. There is no associated pleural effusion. No additional definite nodules are identified. The images obtained show prominent filling defects within the right main pulmonary artery and extending into right pulmonary artery branches. This is consistent with prominent pulmonary embolism. Please note that the peripheral vessels especially at the left lung base were not as well opacified and additional thrombi in this region cannot be excluded.

No significant degree of hilar or mediastinal lymphadenopathy is noted.

IMPRESSION-

Moderate to large sized right pulmonary artery pulmonary embolism with thrombus extending into the more distal branches.

Nodule noted in the superior segment of the right lower lobe, suspicious for metastasis in view of the known history of uterine carcinoma.

A preliminary report was generated immediately following completion of the study and the findings were discussed with [REDACTED]

CT STUDY OF THE ABDOMEN AND PELVIS-

Images were obtained through the abdomen initially without contrast infusion followed by contrast-enhanced imaging of the abdomen and pelvis.

Indication- Metastatic endometrial carcinoma.

The initial nonenhanced images show a somewhat poorly defined mass within the dome of the liver. This measures up to 3 cm in diameter. Somewhat better defined low density is noted superiorly and medially within the right lobe of the liver with additional tiny subcentimeter lucency noted at the mid anterior aspect of the right lobe and also along the posterior edge of the liver. A small peripheral inferior lucency is seen as well measuring up to 2.7 cm in diameter. Images of the pancreas are unremarkable. The identified lucency at the edge of the liver near the right adrenal

[page 10 of 22]
may in fact be of adrenal origin, although this may be within the liver parenchyma adjacent to the adrenal. There is a cystic focus noted in the region of the splenic hilus measuring 1.7 cm in diameter. There are abnormally enlarged retroperitoneal nodes. At the left renal hilus, a 2.2 cm node is noted. Slightly farther inferiorly a node is seen measuring up to 2.1 cm in diameter. These are suspicious for retroperitoneal metastases. No significant lymphadenopathy is seen within the pelvis or within the inguinal canal. The bowel pattern is unremarkable. The kidneys are functioning bilaterally with no significant renal cortical mass lesion identified.

IMPRESSION-

There are several small to moderate sized liver metastases strongly suspected, as described above.

Moderately enlarged retroperitoneal lymph nodes are identified to the left of the abdominal aorta consistent with metastatic lymphadenopathy.

No significant abnormal mass is seen within the pelvis to suggest recurrent or residual disease within the pelvis in this patient with known history of endometrial carcinoma.

Interpreted by-

JOB#

+25

RELEASED BY

[page 11 of 22]
Click icon to view images for patient.

Pat. Name	Adm. Date	Sex	Age	Location	Relationship	Allergies	Adm. Diagnosis	Birth Date
⊕ [REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]		NKA	(V67.00) FOLLOW-UP SURGERY NOS	[REDACTED]
	+25							

Report for [REDACTED] (MRN: [REDACTED])

View Images

TEST: US TRANSVAGINAL NON OB

Collected Date & Time: [REDACTED] -15

Result Name	Results	Units	Reference Range
TRANSCRIPTION	[REDACTED]		
READ BY	[REDACTED]		

READ BY

US TRANSVAGINAL NON

OB

JOB [REDACTED] -15

TRANSVAGINAL PELVIC ULTRASOUND, [REDACTED] -15

Indication- [REDACTED]-year-old female with severe vaginal bleeding.

Findings-

The uterus is anteverted and measures 10.1 x 6.5 x 6.4 cm on transvaginal ultrasound. No focal myometrial abnormality is identified. There is fluid in the endometrial cavity as well as echogenic thickening measuring approximately 4 cm in length and up to 2 cm in AP diameter. No vascularity is seen within this thickening which may represent blood clots or debris. In addition, there is a more echogenic-appearing apparent mass in the cervix slightly to the left of midline measuring 3.3 x 3 x 2.7 cm with abundant arterial flow within it. It is uncertain whether this is within the wall of the cervix or projecting into the cervical canal. Small nabothian cysts are seen adjacent to it.

The right ovary measures 3.4 x 2.5 x 3.1 cm and contains small follicles as well as a hypoechoic region measuring 2 x 1.8 x 1.6 cm with peripheral arterial flow but no central vascularity. This may represent hemorrhagic cyst and solid mass is less likely. The left ovary contains an anechoic cyst measuring 3 x 3 x 3.1 cm. No other adnexal masses are seen and there is no free fluid.

IMPRESSION-

There is a slightly echogenic mass in the cervix measuring approximately 3 cm demonstrating abundant vascularity. This may be within the wall of the cervix or projecting into the cervical canal. This may be a neoplasm but large cervical polyp is not excluded. In addition, there is fluid and echogenic material within the endometrial cavity without vascularity, likely blood clots, although solid mass is not entirely excluded.

There is a 3 cm simple-appearing cyst in the left ovary. In addition, a hypoechoic structure measuring up to 2 cm in the right ovary is seen without internal vascularity. This is likely hemorrhagic cyst. Follow-up ultrasound is suggested to monitor for

[page 12 of 22]
[REDACTED]

resolution of these findings.

The results were discussed with [REDACTED] immediately following the examination.

Interpreted by- [REDACTED]

[REDACTED]

-15

RELEASED BY [REDACTED]

[REDACTED]

[page 13 of 22]
Patient: [REDACTED]
Patient phone: [REDACTED]
Location: [REDACTED]

Ordering Physician: [REDACTED]

Sex: [REDACTED] DOB: [REDACTED]
Patient Type: Outpatient
MR#: [REDACTED]
Account#: [REDACTED]
Physician phone: [REDACTED]
Physician fax: [REDACTED]

REF: [REDACTED]
ADM: [REDACTED]
ATT: [REDACTED]
CC: [REDACTED]
PCP: [REDACTED]

Final Result

Procedure(s) Performed:
CT CHEST W CONTRAST

Exam Date: [REDACTED] +1518

Accession #: [REDACTED]

Diagnosis: Malignant neoplasm of corpus uteri, except isthmus
Reason for Exam: malig neopl of corpus uteri,except isthmus

CT CHEST W CONTRAST, CT ABDOMEN & PELVIS W CONTRAST - [REDACTED] +1518

Indication: [REDACTED]-year-old female with history of endometrial carcinoma for followup assessment.

Comparison: [REDACTED] +1322

Technique: Following oral contrast and during infusion of 100 mL of Optiray-320, 5 mm scans were obtained through the chest, abdomen, and pelvis. Delayed scans through the abdomen and pelvis during the peak excretory phase were obtained. Coronal and sagittal reconstructions were obtained.

Findings:

CT Chest:

There is no axillary, mediastinal, or hilar lymphadenopathy. A small linear opacity in the left side of the anterior mediastinal fat measures 5 x 9 mm and has not changed significantly when compared with multiple previous studies, including CT [REDACTED] insignificant. There are no pleural or pericardial effusions.

+24

Lung windows demonstrate linear atelectasis or fibrosis in the right lower lobe, unchanged. A tiny linear opacity in the right upper lobe is stable since [REDACTED] as is a right lower lobe pleural-based tiny opacity. Minimal linear atelectasis is seen in the lingula. The lungs are otherwise clear.

CT Abdomen and Pelvis:

There is been marked interval improvement. A subcentimeter subtle low density region is seen in the medial segment of the left lobe at site of previously seen large metastasis. The remainder of the serosal metastases previously seen have resolved. A tiny low-density focus anterolaterally in the dome is likely a cyst and is unchanged. A small enhancing focus at the liver dome is not as well seen on the current study as on previous has not changed significantly.

[page 14 of 22]
[REDACTED]

The gallbladder, pancreas, and adrenals are unremarkable. The spleen measures 13.8 cm in AP diameter, increased, and 11.2 cm in craniocaudad dimension, also slightly increased. Splenic vessels are normal in appearance. Both kidneys demonstrate prompt symmetrical function and excretion and are without focal lesion. The aorta is normal in caliber.

Stomach, small bowel, and appendix are unremarkable. The colon is normal in overall appearance. There is diffuse mild wall thickening in the sigmoid colon which is relatively underdistended. There is no surrounding induration. This finding is slightly more pronounced than on previous study. The patient has had a total hysterectomy and surgical clips are seen in the pelvis. There is a small umbilical hernia at site of surgery with protrusion of transverse colon and fat, unchanged. There is also an abdominal wall hernia to the right of midline slightly more inferiorly containing small bowel loops with no evidence for obstruction. This is new when compared previous study.

The large omental masses previously seen have resolved. There are very tiny opacities in the left para-aortic region but the large node previously seen has resolved. Complex fluid previously seen in the pelvis has resolved, as have left pelvic masses.

IMPRESSION:

CT of the chest is unremarkable, with no mass or infiltrate.

There is been marked interval improvement in the abdomen and pelvis, with resolution of previously seen omental metastases, complex fluid, and lymphadenopathy. There is a subcentimeter low-density region adjacent to the falciform ligament at site of previously seen metastasis. Serosal liver metastases have otherwise resolved.

The sigmoid colon contains oral contrast but demonstrates diffuse mild wall thickening which is more pronounced than on previous study. There is no surrounding induration. The findings are nonspecific. Colitis is considered and clinical correlation is suggested.

The spleen is mildly enlarged, and this is of uncertain etiology.

Signed by: [REDACTED]

Signed By: [REDACTED]

Released Date/Time: [REDACTED] +1518

Transcribed By:

[page 15 of 22]
Patient: [REDACTED]

Patient phone: [REDACTED]

Location: [REDACTED]

Ordering Physician: [REDACTED]

Sex: [REDACTED]

Patient Type:

MR#:

Account#:

Physician phone:

Physician fax:

DOB: [REDACTED]

Outpatient

REF:

ADM:

ATT:

CC:

Final Result

Procedure(s) Performed:

CT CHEST W CONTRAST

CT ABDOMEN & PELVIS W CONTRAST

Diagnosis: Ovarian ca
Elevated CA-125
Ovarian ca
Elevated CA-125

Reason for Exam: Ovarian ca
Elevated CA-125
Ovarian ca
Elevated CA-125

Exam Date: [REDACTED] +1322

Accession #: [REDACTED]

ATTENTION

POSTCONTRAST CT OF THE CHEST, ABDOMEN, AND PELVIS, [REDACTED] +1322

Indication: [REDACTED]-year-old female with endometrial carcinoma, increased CA 125.

Technique: Following oral contrast and during infusion of 120 ml of Optiray 320, 5-mm scans were obtained through the chest, abdomen, and pelvis. Delayed scans during the peak excretory phase were also obtained through the abdomen and pelvis. Coronal and sagittal reconstructions were obtained. Comparison is made with the previous CT chest of

[REDACTED] and CT abdomen and pelvis of [REDACTED] +1261

Findings:

CT chest:

There is no axillary, mediastinal, or hilar lymphadenopathy. There are no pleural or pericardial effusions.

Lung windows demonstrate a faint linear opacity in the right upper lobe (image 14), and this was present on earlier studies including CT of [REDACTED]. A nodular opacity measuring under 4 mm is seen in the superior segment of the right lower lobe which is also unchanged since [REDACTED]. A small focus of pleural-based thickening in the lateral aspect of the right lower lobe seen on previous study is less distinct on the current examination but has not definitely changed, and this was also present earlier. There is now bilateral interstitial thickening which may be due to limited inspiration or vascular crowding. No other nodules are seen.

CT abdomen and pelvis:

[page 16 of 22]
+111

The liver is top normal in size. Along the anterior margin of the dome of the liver, there is an enhancing lesion measuring under 1 cm which was present on previous CT of [REDACTED] and may be a small hemangioma. More inferiorly, a tiny cyst is suspected, also unchanged. No other focal lesion is seen within the liver itself. There is a low density lesion in the falciform ligament consistent with serosal metastasis measuring 2.4 cm, and a small nodule is seen adjacent to it. Other similar small serosal metastases are suspected adjacent to the ligamentum venosum between the lateral segment and caudate. These lesions are new since previous study. In addition, there are large masses seen inferior to the right lobe of the liver and extending down the right side of the abdomen which have much increased in size since previous study. This includes a conglomerate mass of mixed density measuring 2.6 x 4.3 cm, and the omental metastases extending more inferiorly measure over 9 cm in AP diameter and 2.6 cm in thickness, much increased. Nodular peritoneal metastases are also seen in the left upper quadrant, and numerous peritoneal metastases extend inferiorly on the left, much increased. A large nodule anterior to the pancreatic head has also increased.

The gallbladder, pancreas, spleen, and adrenals are unremarkable. Both kidneys demonstrate prompt symmetrical function and excretion and are without focal lesion.

Stomach and small bowel loops are normal in appearance. Oral contrast extends to the rectum, and the colon and appendix are normal in appearance.

The patient has had a total hysterectomy. There is high density fluid in the dependent portion of the pelvis, new since previous study. There is either a higher density locule along the left lateral margin of the fluid or this may be adjacent mass, and there is also an anterior 2.2-cm component in the left pelvis which may be complex fluid or possible tumor and this is smooth walled. There is a 1.6-cm periaortic node inferior to the left renal vein with no significant change. No other retroperitoneal adenopathy is seen.

IMPRESSION:

There has been marked interval progression of disease, with marked increase in peritoneal metastases and right-sided omental cake. There are also serosal metastases seen along the liver margin, new since previous study. Complex high density fluid is seen in the pelvis.

~+24

CT of the chest demonstrates some vascular crowding at the lung bases. Two small lung nodules are stable since [REDACTED]. The lungs are otherwise clear.

Interpreted by [REDACTED]

Job [REDACTED]

[page 17 of 22]
[REDACTED]			
DATE		CA 125	REFERENCE RANGE
[REDACTED]	+22	217.2	0.0-34.0
[REDACTED]	+36	202.1	0.0-34.0
[REDACTED]	+104	14.4	0.0-34.0
[REDACTED]	+125	13.4	0.0-34.0
[REDACTED]	+188	13	0.0-34.0
[REDACTED]	+217	13.7	0.0-34.0
[REDACTED]	+310	11.3	0.0-34.0
[REDACTED]	+405	11	0.0-34.0
[REDACTED]	+496	15.3	0.0-34.0
[REDACTED]	+594	37.4	0.0-34.0
[REDACTED]	+689	23.2	0.0-34.0
[REDACTED]	+783	16.8	0.0-34.0
[REDACTED]	+878	18.6	0.0-34.0
[REDACTED]	+983	28.2	0.0-34.0
[REDACTED]	+1085	45.3	0.0-34.0
[REDACTED]	+1263	552.6	0.0-34.0
[REDACTED]	+1311	1532	0.0-34.0
[REDACTED]	+1837	10.6	0.0-34.0
[REDACTED]	+1900	16.3	0.0-34.0
[REDACTED]	+1928	11.7	0.0-34.0
[REDACTED]	+1984	11.2	0.0-34.0

CA 125's from patient's material record

[REDACTED]

[page 18 of 22]
LAB VALUES

Patient Name: [REDACTED]

Age: [REDACTED]

Lab Values :

Cancer Antigen (CA)

Print

[page 19 of 22]
+1522

Current Medications

Arixtra 5 MG/0.4ML Solution as directed
Multi Complete Capsule as directed
Fish Oil 1000 MG Capsule 1 capsule Once a day
Bisoprolol-Hydrochlorothiazide 2.5/6.25 Tablet TAKE 1 TABLET DAILY
Lovastatin 20MG Milligram Tablet TAKE 1 TABLET DAILY
Medication List reviewed and reconciled with the patient

Past Medical History

Hypercholesterolemia
Hypertension

Surgical History

appendectomy
hysterectomy, total with bilateral salpingo-oophorectomy (BSO)

Family History

Mother: colon cancer

Social HistoryTobacco Use:

Tobacco Use/Smoking Are you a:
nonsmoker.

Drugs/Alcohol:

Alcohol Screen Did you have a drink containing alcohol in the past year?: No,
Points: 0.

Miscellaneous:

Children: two children
Marital status: married.

Allergies

N.K.D.A.

Hospitalization/Major Diagnostic Procedure

No Hospitalization History.

Review of SystemsGeneral/Constitutional:

generalized weakness Denies. Trouble Sleeping Denies. Alopecia Denies.

Reason for Appointment

1. Met. Endometrial ca
2. CT results

History of Present IllnessOncology History:

The patient is a pleasant 60-year-old woman with metastatic uterine cancer now presents for followup. She began second line treatment for recurrent metastatic disease to smoke ago and a CT of the abdomen and pelvis performed today and reveals no residual cancer. In addition, her most recent CEA 125. From 2 weeks ago was markedly improved at 12.6. She is asymptomatic and tolerating chemotherapy extremely well.

Vital Signs

Temp 99.2 F, HR 83 /min, BP 157/96 mm Hg, Ht 66 in, Wt 203 lbs, Wt-kg 92.08 kg, BMI 32.76 Index, RR 18 /min, Ht-cm 167.64 cm.

ExaminationGeneral Examination:

ECOG Score 0.

GENERAL APPEARANCE: in no acute distress, well developed, well nourished.

HEAD: normocephalic, atraumatic.

EYES: pupils equal, round, reactive to light and accommodation.

EARS: normal.

ORAL CAVITY: mucosa moist.

THROAT: clear.

NECK/THYROID: neck supple, full range of motion, no cervical lymphadenopathy.

LYMPH NODES: no palpable adenopathy.

SKIN: no suspicious lesions, warm and dry.

HEART: no murmurs, regular rate and rhythm, S1, S2 normal.

LUNGS: clear to auscultation bilaterally.

ABDOMEN: normal, bowel sounds present, soft, nontender, nondistended.

EXTREMITIES: no clubbing, cyanosis, or edema.

NEUROLOGIC: nonfocal exam, motor strength normal upper and lower extremities, sensory exam intact.

Assessments

+1522

Patient: [REDACTED] DOB: [REDACTED] Progress Note [REDACTED]

[page 20 of 22]
Denies Change in appetite, denies.
Denies Chills. Denies Fatigue, that is
intermittent. Denies Fever. Denies 'B'
symptoms. Denies Lightheadedness. Night
sweats denies. Denies Sleep disturbance.
Denies Weight gain. Denies Weight loss.

Allergy/Immunology:

Denies Blistering of skin.
Denies Congestion. Denies Hives.
Denies Rash.

Ophthalmologic:

Denies Blurred vision. Denies Discharge.
Denies Dry eye.

ENT:

Denies Decreased hearing.
Denies Decreased sense of smell.

Endocrine:

Denies Difficulty sleeping.
Denies Dizziness.

Respiratory:

Denies Cough, denies.
Denies Hemoptysis. Denies Sputum
production. Denies Wheezing.

Cardiovascular:

Denies Chest pain. Denies Chest pain
with exertion. Denies Claudication.
Denies Difficulty laying flat.
Denies Dizziness. Denies Dyspnea on
exertion. Denies Irregular heartbeat.

Gastrointestinal:

Denies Abdominal pain. Denies Blood in
stool. Denies Change in bowel habits.
Denies Constipation, denies.
Denies Malena. Denies Diarrhea, denies.
Denies Black Stool. Denies Heartburn.
Denies Hematemesis. Denies Nausea.
Denies Vomiting.

Hematology:

Denies Excessive bruising.
Denies Prolonged bleeding. Denies Recent
transfusion. Denies Swollen glands.

Genitourinary:

Denies Blood in urine. Denies Dysurea.
Denies Hematuria. Denies Painful urination.

Musculoskeletal:

Denies Leg cramps, denies.
Denies Muscle aches, denies.

Skin:

Denies Acne. Denies Blistering of skin.
Denies Dry skin. Denies Hives.
Denies Itching. Denies Rash.

Neurologic:

Denies Dizziness, denies. Denies Loss
of consciousness. Denies Black Outs.
Denies Headache, denies. Denies Seizures.

Psychiatric:

Denies Anxiety, denies.
Denies Auditory/visual hallucinations.
Denies Delusions. Denies Difficulty sleeping.
Denies Loss of appetite.

1. Malignant neoplasm of corpus uteri, except isthmus - 182.0
(Primary)

Metastatic uterine cancer-complete remission

Will resume chemotherapy next week with Taxol 50 mg/m weekly x3
and carboplatin AUC 2 weekly x3

Zofran 16 mg IV weekly x3

Neupogen 480 g subcutaneous daily x2 after her first 2 doses of
chemotherapy and Neulasta 6 mg subcutaneous after her third dose of
chemotherapy

Followup in 5 weeks with CBC, CMP.

Explained to patient that there is no right or right long way to proceed
at this time and that patient include discontinue treatment versus
continued given lack of side effects. The patient has chosen to continue
chemotherapy and we'll recheck a CT in 4 months at which time we will
reach a decision point.
CBC every week of treatment.

Labs

Lab: CBC With Differential/Platelet**

Lab: Comp. Metabolic Panel (14)

Electronically signed by

Sign off status: Pending

+1522

+1522

Patient: DOB: Progress Note:

[page 21 of 22]
[REDACTED] +217

[REDACTED]
[REDACTED]
Re: [REDACTED]

Dear [REDACTED]

I saw your patient, [REDACTED], in the office today. As you know, she is a [REDACTED]-year-old woman with widely metastatic endometrial cancer who initially presented to us in [REDACTED] ~+5. She received eight cycles of chemotherapy with Taxol, Adriamycin and Cisplatin. She tolerated treatment extremely well. Follow-up CT scans of the chest, abdomen and pelvis performed roughly 1.5 weeks ago were completely unremarkable. There was no evidence of residual cancer.

In addition, her CA 125 is markedly decreased at 13.

Ms. [REDACTED] has obtained complete remission with chemotherapy. At this time, we will simply observe her. She will follow up with us again at the beginning of [REDACTED] with a CA 125.

I will keep you abreast of any further oncologic issues and would like to thank you for allowing me to participate in your patient's care.

Sincerely,

[REDACTED]
cc: [REDACTED]

[page 22 of 22]
Report for [REDACTED] (MRN: [REDACTED])

TEST: [REDACTED]
Collected Date & Time: [REDACTED] +16

Result Name	Results	Units	Reference Range
Cons			

CONSULTATION REPORT

NAME: [REDACTED] DOB: [REDACTED]
PAT. LOC: [REDACTED] PAT. TYPE: RC
ADMIT: [REDACTED] +16 DISCHARGE: [REDACTED]
DATE OF CONSULTATION: [REDACTED] +16

CONSULTANT: [REDACTED]

ATTENDING: [REDACTED]

REASON FOR CONSULTATION: STAGE IVB SEROUS PAPILLARY
ENDOMETRIAL ADENOCARCINOMA,
STATUS POST SURGERY ON [REDACTED] +0

HISTORY: This is a [REDACTED]-year-old female with a history of stage IVB serous papillary endometrial adenocarcinoma who had surgery with tumor debulking on [REDACTED]. She was found to have diffusely metastatic intraabdominal carcinomatosis. The patient has recovered from surgery. Today she was seen with no specific complaints. The staples were removed by [REDACTED]. The incisional is completely healed. The abdomen is soft. Pelvic exam was not performed.

IMPRESSION: THE ENDOMETRIUM WITH DIFFUSE INTRAABDOMINAL METASTASES INCLUDING APPENDIX, OMENTUM, PELVIC, PERITONEUM INCLUDING RIGHT AND LEFT PELVIC LYMPH NODES AND AORTIC LYMPH NODE METASTASES. METASTATIC STAGE IVB PAPILLARY ADENOCARCINOMA OF

RECOMMENDATIONS: I had a long discussion with the patient and her husband. Based on metastatic serous papillary adenocarcinoma of the endometrium, I would recommend chemotherapy. This was discussed in detail the risks, complications and prognosis was also explained to the patient. The patient has been referred to medical oncologist, [REDACTED]. The patient has made an appointment today and plans to start chemotherapy in 1-2 weeks. I will follow the periodically during her chemo and after her chemotherapy.

Thank you.

Source: NCI Genomic Data Commons file 50df77bf-5672-4f01-acf6-d45aa491cd74 (ER0170 ER-ADIN Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).